Surgical pathology report (de-identified scan), TCGA case TCGA-QG-A5Z2, project TCGA-COAD (Colon Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-QG-A5Z2-01A (Primary Tumor).

[page 1 of 2]
Report

ICD-0-3
Adenocarcinoma NOS 8140/3
Site Cecum C18.0
JW 4/16/13

---- SURGICAL PATHOLOGY ----

SURGICAL PATHOLOGY

PORT

Accession No.

Date obtained:

RIGHT HEMICOLECTOMY

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

colon cancer

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

colon cancer

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

GROSS DESCRIPTION:

The specimen consists of a 27.8 cm in length segment of right colon with 4.7 cm of attached terminal ileum. The specimen is stapled at both ends with a moderate amount of attached fat. The serosa is tan-pink to red, smooth and glistening. There is a 7.2 x 0.8 cm intact vermiform appendix.

Opening reveals a tan-brown smooth glistening ileal mucosa with normal folds. The ileocecal valve is tan-yellow and thickened. The colonic mucosa displays a 3.8 x 2.6 x 0.8 cm tan-red slightly raised polypoid mass that is 9.3 cm from the proximal resection margin, and 19.8 cm from the distal resection margin. Sectioning through the mass reveals a focal area of invasion going into the underlying muscle layer. The mass does not extend to the inked serosal surface. The mass is 7.3 cm from the mesenteric resection margin.

The remaining colonic mucosa is tan-brown smooth and glistening with a 1.0 x 1.0 x 0.3 cm submucosal mass grossly consistent with a submucosal lipoma. There is a moderate amount of endoscopy tattooing adjacent to the polypoid mass. Sectioning through the attached fat reveals multiple tan-pink rubbery lymph nodes.

Representative sections are submitted as follows: 1- proximal resection margin; 2- distal resection margin; 3-9- entire mass with underlying fat and possible inked serosa; 10- mesenteric resection margin closest to mass; 11- submucosal lipoma; 12- appendix; 13- ileocecal valve; 14-18- multiple whole lymph nodes; 19-20- one bisected lymph node in each; 21- multiple whole lymph nodes.

MICROSCOPIC EXAM

DIAGNOSIS:

Colon, right, hemicolectomy:

- INVASIVE ADENOCARCINOMA, LOW GRADE (MODERATELY DIFFERENTIATED), (SEE CANCER SUMMARY)
- ALL MARGINS FREE OF TUMOR
- 23 LYMPH NODES NEGATIVE FOR MALIGNANCY (0/23)

[page 2 of 2]
- TATTOO PIGMENT IDENTIFIED
- UNREMARKABLE APPENDIX
- SUBMUCOSAL LIPOMA

Surgical Pathology Cancer Case Summary

SPECIMEN: Terminal ileum, cecum, appendix, ascending colon
PROCEDURE: Right hemicolectomy
TUMOR SITE: Cecum
TUMOR SIZE: 3.8 x 2.6 x 0.8 cm
MACROSCOPIC TUMOR PERFORATION: Not identified
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Low grade (moderately differentiated)
MICROSCOPIC TUMOR EXTENSION: Tumor penetrates into the muscularis propria

MARGINS:

Proximal: Uninvolved by invasive carcinoma
Distal: Uninvolved by invasive carcinoma
Mesenteric: Uninvolved by invasive carcinoma

TREATMENT EFFECT: No prior treatment
LYMPH-VASCULAR INVASION: Not identified
PERINEURAL INVASION: Not identified
TUMOR DEPOSITS: Not identified
LYMPH NODES: 0 metastases (23 nodes examined)
PATHOLOGIC STAGING: (pTNM): pT2, pN0, pMx

PATHOLOGIST

Signed

(End of report)

Source: NCI Genomic Data Commons file 19a8f09c-d64b-4d5b-8118-a45c33994765 (TCGA-QG-A5Z2.E997748F-FB20-4CF3-8621-966181B7AF2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).